Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6814, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6814-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Case ID	Subject ID	Formatted Path Report
[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Resection of rectum Specimen size: Not specified Tumor site: Rectum Tumor size: 15 x 7.5 x 10 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Pericolonic tissues Lymph nodes: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 68725a9d-9131-4d45-8d55-47d39d062bdb (TCGA-F5-6814.51379639-FD60-4561-91C8-76941068C36C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).